Somatic mutation profile of tumor specimen C3N-02068-01 (aliquot CPT0109860007) from CPTAC case C3N-02068, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 47.4 years (17,306 days).
Specimen C3N-02068-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44047db3-17a3-4ffd-954d-a5acc84aa318.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02068-71 (Blood Derived Normal), aliquot CPT0139430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a1f813e-2ea1-409b-82b0-9489a7402e84

The open-access MAF lists 50 somatic variants for this specimen: 36 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, Frame Shift Del 4, Frame Shift Ins 2, 5'Flank 2, 3'UTR 2, Nonsense Mutation 2, 5'UTR 1, Splice Region 1, Intron 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 93/412 reads (23%) | hotspot (GDC flag); catalogued as rs5030818, CM941381, CM961432, COSV56542817, COSV56554019, COSV56564848; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASS | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 90/437 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs942519564, COSV100741794; called by muse, varscan2
- CDS2 | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV66897950; called by muse, mutect2, varscan2
- CPEB3 | c.188del p.P63Rfs*19 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as rs751359395; called by mutect2, pindel, varscan2
- FLNA | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 9/263 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs375463904; ClinVar: uncertain significance; called by muse, mutect2
- MAGEE1 | c.754C>G p.R252G | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV63909207; called by muse, mutect2, varscan2
- MAMSTR | c.1227C>A p.D409E (on ENST00000318083 / NM_001130915.2; = p.D306E on NM_182574.2) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1168594192; called by muse, mutect2, varscan2
- MICA | c.125A>G p.Q42R | Missense Mutation (SNP) | VAF 59/283 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs759993018; called by muse, mutect2, varscan2
- SLC66A1 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1048032411; called by muse, mutect2, varscan2
- UTP3 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747804289, COSV54660870; called by muse, mutect2, varscan2
- VSTM2L | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65096406; called by muse, mutect2, varscan2
- ACSM2B | c.1228A>G p.I410V | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- AMN1 | c.655T>C p.C219R | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARID1B | c.1397_1419delinsC p.G466Afs*29 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by pindel, varscan2*
- BRPF1 | c.1320G>T p.K440N | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- C11orf45 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 38/186 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CC2D2A | c.2809A>C p.I937L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- DPH2 | c.1181A>G p.H394R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EOGT | c.1214+6T>C | Splice Region (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- EPHA10 | c.548T>A p.L183H | Missense Mutation (SNP) | VAF 91/417 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC6 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 40/167 reads (24%) | called by muse, mutect2
- HFM1 | c.4086dup p.V1363Cfs*16 | Frame Shift Ins (INS) | VAF 15/113 reads (13%) | called by mutect2, pindel, varscan2
- INO80B | c.948T>A p.H316Q | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- KLF10 | c.814dup p.V272Gfs*91 | Frame Shift Ins (INS) | VAF 15/95 reads (16%) | called by mutect2, pindel, varscan2
- NCAPH2 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- PAOX | c.961A>T p.N321Y | Missense Mutation (SNP) | VAF 87/355 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKIG | c.152-5_152-2del p.X51_splice | Splice Site (DEL) | VAF 47/301 reads (16%) | called by mutect2, pindel, varscan2
- RAD50 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RSL1D1 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 36/197 reads (18%) | called by mutect2, pindel, varscan2
- RYK | c.618G>C p.L206F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.242); called by muse, varscan2
- SAMD14 | c.893A>G p.E298G (on ENST00000330175 / NM_001257359.2; = p.E326G on NM_174920.4) | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SDF2L1 | c.603G>C p.K201N | Missense Mutation (SNP) | VAF 83/378 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLC6A19 | c.1346T>C p.I449T | Missense Mutation (SNP) | VAF 80/363 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SP140 | c.2042G>A p.S681N | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ST8SIA6 | c.466G>C p.V156L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2
- SUPT5H | c.985del p.R329Gfs*53 | Frame Shift Del (DEL) | VAF 69/328 reads (21%) | called by mutect2, pindel, varscan2
- EPHA10 | c.549C>A p.L183= | Silent (SNP) | VAF 91/419 reads (22%) | called by muse, mutect2, varscan2
- FAM114A2 | c.51C>A p.P17= | Silent (SNP) | VAF 101/504 reads (20%) | called by muse, mutect2, varscan2
- FMR1NB | c.525T>A p.A175= | Silent (SNP) | VAF 9/275 reads (3%) | called by muse, mutect2
- KLHL40 | c.1353G>T p.V451= | Silent (SNP) | VAF 65/275 reads (24%) | called by muse, mutect2, varscan2
- NPR3 | c.159C>A p.I53= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1250628318; called by muse, mutect2, varscan2
- RALGAPA1 | c.3621C>G p.A1207= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- SOS1 | c.66A>G p.L22= | Silent (SNP) | VAF 36/212 reads (17%) | catalogued as rs770539511; called by muse, mutect2, varscan2
- ACSS3 | c.*4448T>C | 3'UTR (SNP) | VAF 6/34 reads (18%) | catalogued as rs1355517414; called by muse, mutect2, varscan2
- ATP11AUN | n.1093C>T | RNA (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- COPS4 | c.887-1315A>C | Intron (SNP) | VAF 16/106 reads (15%) | called by muse, varscan2
- DCAF17 | c.*1480A>C | 3'UTR (SNP) | VAF 90/338 reads (27%) | called by muse, mutect2, varscan2
- RASAL2 | chr1:178093185 C>A | 5'Flank (SNP) | VAF 60/253 reads (24%) | catalogued as rs1449037271; called by muse, mutect2, varscan2
- TTC21B | c.-32C>T | 5'UTR (SNP) | VAF 43/159 reads (27%) | called by muse, mutect2, varscan2
- YIPF6 | chrX:68498995 G>A | 5'Flank (SNP) | VAF 27/230 reads (12%) | called by muse, mutect2, varscan2
